Gene-level copy-number profile of tumor specimen TCGA-E7-A4IJ-01A from TCGA case TCGA-E7-A4IJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.7 years (20,723 days).
Specimen TCGA-E7-A4IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3961918c-31d5-41ae-8b8c-3dfdaa278def.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A4IJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0c701b2-4b17-4397-8295-72c85ccfee15

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 506; copy number 3: 3,763; copy number 4: 19,994; copy number 5: 16,431; copy number 6: 4,379; copy number 7: 5,089; copy number 8: 3,691; copy number 9: 3,663; copy number 10: 451; copy number 11: 664; copy number 12: 62; copy number 13: 684; copy number 14: 11; copy number 15: 135; copy number 16: 128; copy number 17: 34; copy number 18: 19; copy number 19: 26; copy number 22: 15; copy number 26: 61; copy number 30: 2; copy number 43: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A4IJ-01A-31D-A26L-01): tumor purity 0.48, ploidy 5.43, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,962 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,036,321–174,995,308, 826 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr1:174,849,667–193,091,777, 284 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr2:95,542,730–103,019,900, 175 genes, copy number 9 (broad region; genes not listed).
- chr2:139,469,775–172,109,982, 384 genes, copy number 9–16 (broad region; genes not listed).
- chr2:180,692,104–182,523,192, 25 genes, copy number 10 (within-gene range 7–10): SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P.
- chr3:12,004,388–12,539,623, 10 genes, copy number 9 (within-gene range 6–9): SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P.
- chr5:58,198–25,911,234, 414 genes, copy number 9–10 (broad region; genes not listed).
- chr5:74,721,206–75,052,558, 15 genes, copy number 9: GFM2, RNU6-658P, NSA2, FAM169A, RNU6-1330P, AC093214.1, AC010501.2, AC010501.1, AC116337.4, AC116337.3, AC116337.1, AC116337.2, RPL27AP5, AC093259.1, GCNT4.
- chr6:15,522,195–24,719,998, 116 genes, copy number 12–16 (within-gene range 7–16) (broad region; genes not listed).
- chr6:42,224,931–44,553,281, 93 genes, copy number 9–18 (broad region; genes not listed).
- chr6:49,823,712–53,369,009, 71 genes, copy number 10 (broad region; genes not listed).
- chr7:70,972–16,645,817, 276 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:16,695,871–63,790,098, 844 genes, copy number 9–14 (broad region; genes not listed).
- chr7:159,231,435–159,233,377, 1 gene, copy number 9: PIP5K1P2.
- chr8:104,590,733–105,804,539, 1 gene, copy number 9 (within-gene range 8–9): ZFPM2.
- chr8:105,142,860–118,111,826, 102 genes, copy number 9 (broad region; genes not listed).
- chr10:42,979,017–45,453,121, 74 genes, copy number 10–15 (broad region; genes not listed).
- chr10:48,153,088–49,115,522, 20 genes, copy number 17 (within-gene range 4–17): FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4.
- chr12:66,767–3,593,973, 90 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr12:4,649,101–15,006,999, 407 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr12:15,112,363–15,155,283, 2 genes, copy number 9: RERG-IT1, RERG-AS1.
- chr13:25,301,556–28,295,335, 63 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr13:39,856,710–41,084,006, 22 genes, copy number 11: AZU1P1, SNORD116, LINC00598, LINC00332, RPL17P51, RNY3P9, RN7SKP2, AL133318.1, FOXO1, RLIMP1, MIR320D1, MRPS31, Metazoa_SRP, SLC25A15, MIR621, TPTE2P5, CYCSP34, AL590064.1, SUGT1P3, ELF1, RGS17P1, WBP4.
- chr13:49,220,338–52,587,095, 89 genes, copy number 10–15 (within-gene range 2–15) (broad region; genes not listed).
- chr18:8,545,635–11,390,729, 68 genes, copy number 9 (broad region; genes not listed).
- chr19:27,638,483–30,713,538, 66 genes, copy number 16–30 (broad region; genes not listed).
- chr20:30,294,550–45,879,122, 444 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 13–17 (broad region; genes not listed).
- chr22:25,212,085–28,848,559, 97 genes, copy number 12–43 (within-gene range 6–43) (broad region; genes not listed).
- chr22:29,073,035–31,530,634, 114 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr22:31,490,150–31,521,592, 2 genes, copy number 11: AL096701.4, H2AZP6.
- chr22:32,507,820–33,058,381, 1 gene, copy number 14 (within-gene range 7–14): SYN3.
- chr22:32,783,177–34,724,919, 21 genes, copy number 14–26: Z73495.1, TIMP3, Z83846.1, LINC01640, Z82198.1, Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
